CPTAC case C3N-00294 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ceec9e64-83fc-48ce-b7cd-bbab1b9ad14d

Demographics
Sex at birth: male; Race: white; Year of birth: 1958; Vital status: Alive; Country of birth: Poland.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lower lobe, lung; Age at diagnosis: 57.9 years (21,155 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2b; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,848 days (5.1 years); Progression or recurrence: yes; Days to last follow up: 1,848 days (5.1 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 6 cm (a second GDC size field records 4.5 cm); Lymph node involvement: Positive; Lymph nodes positive: 1; Lymph nodes tested: 14; Margin status: Uninvolved.

Follow-up (5 entries)
- Days to follow up: 370 days (1.0 years); Disease response: With Tumor; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 832 days (2.3 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,042 days (2.9 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 1,042 days (2.9 years); Karnofsky performance status: 100; ECOG performance status: 1.
- Days to follow up: 1,400 days (3.8 years); Disease response: With Tumor; Karnofsky performance status: 100; ECOG performance status: 1.
- Days to follow up: 1,848 days (5.1 years); Disease response: With Tumor; Karnofsky performance status: 100; ECOG performance status: 1.

Other clinical attributes
- Weight: 80 kg; Height: 168 cm; BMI: 28.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 29.3; Cigarettes per day: 15; Tobacco smoking onset year: 1976; Tobacco smoking quit year: 2015; Exposure duration years: 39.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00294-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 0.69 mg.
- Sample C3N-00294-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 530 mg; Time between excision and freezing: 9 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00294-22: Section location: Right Lower Lobe; Percent tumor nuclei: 80; Percent necrosis: 10.
- Sample C3N-00294-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 0.91 mg.
- Sample C3N-00294-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 0.97 mg.
- Sample C3N-00294-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
